CPTAC case C3L-06912 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d6cddbda-9d1c-4b2b-885f-f7c89ff3a7f1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1978; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Brain, NOS; Age at diagnosis: 42.3 years (15,442 days); Year of diagnosis: 2020; Tumor grade: G3.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-06912-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 830 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-06912-21: Section location: Right fronto-temporal; Percent tumor nuclei: 65; Percent necrosis: 0.
- Sample C3L-06912-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
